Somatic mutation profile of cancer-model specimen HCM-CSHL-0669-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0669-C18-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0669-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GX; Age at diagnosis: 39.1 years (14,293 days).
Specimen HCM-CSHL-0669-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd721ccb-86b5-41e8-b460-c3933af689bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0669-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0669-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b501782-46e8-41b6-afa5-8e220a33c4a0

The open-access MAF lists 131 somatic variants for this specimen: 88 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 39, Frame Shift Del 4, Frame Shift Ins 3, Intron 2, Nonsense Mutation 2, Splice Region 2, 3'Flank 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 278/568 reads (49%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, varscan2
- EDA | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 856/862 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs132630317, CM980594; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 166/374 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 317/362 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.14191G>A p.V4731M | Missense Mutation (SNP) | VAF 206/539 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs770972847, COSV67979590; called by muse, mutect2, varscan2
- ANKRD52 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 256/612 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs755787647; called by muse, varscan2
- ANPEP | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 355/760 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs865803419; called by muse, varscan2
- ARMC4 | c.2792C>A p.A931E | Missense Mutation (SNP) | VAF 134/296 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV59459500; called by muse, mutect2, varscan2
- CLCA4 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs372259034; called by muse, mutect2, varscan2
- DHPS | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs547740533, COSV52952527; called by muse, varscan2
- DNAI4 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 237/533 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1200831254; called by muse, mutect2, varscan2
- DOP1A | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 257/534 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1262635384; called by muse, varscan2
- ENPP2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 178/660 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs774437303, COSV99309679; called by muse, varscan2
- ETNPPL | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1484591118; called by muse, varscan2
- FBXW12 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 80/519 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1350657787; called by muse, mutect2, varscan2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 220/489 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, varscan2
- HMMR | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1356222397; called by muse, mutect2, varscan2
- INPP5D | c.1309G>A p.D437N (on ENST00000445964 / NM_001017915.3; = p.D436N on NM_005541.5) | Missense Mutation (SNP) | VAF 380/816 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs776762956, COSV64035249; called by muse, varscan2
- LCN6 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 272/612 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs564461494, COSV100366548; called by muse, varscan2
- LMBRD1 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 145/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1456368451; called by muse, mutect2, varscan2
- MAGEA6 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 90/472 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV61448878; called by muse, varscan2
- OR4Q3 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59178519; called by muse, varscan2
- OTOL1 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 208/490 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV60006999; called by muse, mutect2, varscan2
- PIK3CG | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 352/793 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV63247659; called by muse, varscan2
- PLEKHG3 | c.3259C>T p.R1087W (on ENST00000394691; = p.R1143W on NM_001308147.2) | Missense Mutation (SNP) | VAF 315/694 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368387962; called by muse, varscan2
- PLXNA4 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 197/440 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.244); catalogued as rs756017390, COSV58157891, COSV58160851; called by muse, mutect2, varscan2
- PNPLA6 | c.3446T>C p.M1149T (on ENST00000414982 / NM_001166111.2; = p.M1101T on NM_006702.5) | Missense Mutation (SNP) | VAF 189/394 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs767497839; called by muse, mutect2, varscan2
- POMT2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 157/381 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); catalogued as rs148466370; ClinVar: uncertain significance; called by muse, varscan2
- RALGDS | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 253/546 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs367807822, COSV64428188; called by muse, varscan2
- TNFSF8 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 184/443 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs758283553; called by muse, mutect2, varscan2
- TRIM64B | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 228/1028 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1310299227, COSV61693694; called by muse, varscan2
- UQCRQ | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 164/444 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as rs557522949; called by muse, varscan2
- ZFHX4 | c.9058T>G p.L3020V | Missense Mutation (SNP) | VAF 205/690 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99267930, COSV99268688; called by muse, varscan2
- ZSCAN4 | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56591445; called by muse, mutect2, varscan2
- ACSF2 | c.1476A>G p.G492= | Splice Region (SNP) | VAF 19/487 reads (4%) | called by muse, mutect2
- ADPRH | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 309/630 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ALPI | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 284/618 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- APC | c.2544dup p.D849Rfs*2 | Frame Shift Ins (INS) | VAF 124/364 reads (34%) | called by pindel, varscan2
- ATAD2 | c.2456A>C p.K819T | Missense Mutation (SNP) | VAF 210/664 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, varscan2
- ATIC | c.696del p.N232Kfs*7 | Frame Shift Del (DEL) | VAF 90/235 reads (38%) | called by mutect2, pindel, varscan2
- C2orf16 | c.2816C>G p.T939R | Missense Mutation (SNP) | VAF 182/424 reads (43%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CCDC170 | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 236/454 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CCDC7 | c.871A>C p.R291= | Splice Region (SNP) | VAF 124/240 reads (52%) | called by muse, varscan2
- CCT3 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 157/360 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.6554T>G p.V2185G (on ENST00000520002; = p.V2184G on NM_033225.6) | Missense Mutation (SNP) | VAF 219/696 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLC1 | c.3863A>G p.E1288G (on ENST00000276297 / NM_001348081.2; = p.E851G on NM_006094.5) | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, varscan2
- DNAH11 | c.3937del p.Y1313Tfs*4 | Frame Shift Del (DEL) | VAF 110/298 reads (37%) | called by pindel, varscan2
- EPHB1 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 280/605 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.9174dup p.I3059Yfs*8 | Frame Shift Ins (INS) | VAF 101/259 reads (39%) | called by mutect2, pindel, varscan2
- GPR135 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 383/797 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIA1 | c.266A>C p.Y89S | Missense Mutation (SNP) | VAF 132/300 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HNRNPU | c.1591G>T p.D531Y (on ENST00000283179; = p.D593Y on NM_004501.3) | Missense Mutation (SNP) | VAF 243/579 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, varscan2
- HNRNPU | c.1590A>T p.E530D (on ENST00000283179; = p.E592D on NM_004501.3) | Missense Mutation (SNP) | VAF 226/537 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IGBP1P2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 538/842 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- KIAA1755 | c.3532T>C p.S1178P | Missense Mutation (SNP) | VAF 282/640 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL4 | c.338A>C p.K113T | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); called by muse, varscan2
- KMT2C | c.2506dup p.S836Ffs*4 | Frame Shift Ins (INS) | VAF 48/260 reads (18%) | called by mutect2, varscan2
- KRAS | c.30_35dup p.A11_G12dup | In Frame Ins (INS) | VAF 248/308 reads (81%) | called by mutect2, varscan2
- LCORL | c.4531C>T p.Q1511* | Nonsense Mutation (SNP) | VAF 160/404 reads (40%) | called by muse, varscan2
- LEUTX | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 251/535 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LGI4 | c.835A>G p.S279G | Missense Mutation (SNP) | VAF 486/1131 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRGUK | c.968T>A p.I323N | Missense Mutation (SNP) | VAF 74/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAK | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 215/457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NEK3 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PANK2 | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 370/724 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA9 | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 248/524 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDHB7 | c.1537C>A p.L513M | Missense Mutation (SNP) | VAF 135/1154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- RAD50 | c.2297A>T p.N766I | Missense Mutation (SNP) | VAF 308/603 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- RASGRF1 | c.932T>G p.I311S | Missense Mutation (SNP) | VAF 236/539 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, varscan2
- RTTN | c.5647G>A p.A1883T | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SLC3A2 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 202/393 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SMAD4 | c.1586del p.L529Yfs*8 | Frame Shift Del (DEL) | VAF 368/532 reads (69%) | called by pindel, varscan2
- TAS1R1 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 402/806 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, varscan2
- TGFBR1 | c.1283A>T p.Y428F | Missense Mutation (SNP) | VAF 154/326 reads (47%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TMUB2 | c.458G>A p.S153N (on ENST00000538716 / NM_001353177.2; = p.S133N on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 556/933 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.071); called by muse, varscan2
- TNS2 | c.948A>T p.E316D (on ENST00000314250 / NM_170754.4; = p.E326D on NM_015319.2) | Missense Mutation (SNP) | VAF 229/514 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TNXB | c.13014T>A p.H4338Q (on ENST00000647633; = p.H4091Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/620 reads (2%) | SIFT tolerated (0.1); PolyPhen benign (0.202); called by muse, mutect2
- TPH2 | c.575del p.K192Sfs*49 | Frame Shift Del (DEL) | VAF 81/222 reads (36%) | called by mutect2, pindel, varscan2
- TRIM46 | c.34T>A p.S12T | Missense Mutation (SNP) | VAF 284/608 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); called by muse, varscan2
- TUBGCP2 | c.2242T>A p.F748I | Missense Mutation (SNP) | VAF 234/547 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ULK3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 185/464 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- UNC80 | c.2325A>T p.Q775H | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.112); called by muse, varscan2
- VLDLR | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 228/434 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZFPM2 | c.2557T>C p.Y853H | Missense Mutation (SNP) | VAF 275/870 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF23 | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 245/530 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ZNF517 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 182/632 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZYX | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 286/571 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANAPC4 | c.1635A>G p.G545= | Silent (SNP) | VAF 121/307 reads (39%) | called by muse, mutect2, varscan2
- APOB | c.4017T>G p.T1339= | Silent (SNP) | VAF 324/692 reads (47%) | called by muse, varscan2
- ARHGEF40 | c.3156C>T p.C1052= | Silent (SNP) | VAF 413/864 reads (48%) | called by muse, mutect2, varscan2
- B3GNT6 | c.795C>T p.F265= | Silent (SNP) | VAF 485/1010 reads (48%) | catalogued as rs782086741; called by muse, mutect2, varscan2
- BMPER | c.1980T>A p.V660= | Silent (SNP) | VAF 225/543 reads (41%) | called by muse, varscan2
- CAPN3 | c.2430C>T p.N810= | Silent (SNP) | VAF 231/531 reads (44%) | catalogued as rs926395403, COSV99782272; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASQ2 | c.897C>T p.P299= | Silent (SNP) | VAF 190/438 reads (43%) | catalogued as rs752053912, COSV99798009; called by muse, mutect2, varscan2
- CD177 | c.288C>T p.S96= | Silent (SNP) | VAF 503/1072 reads (47%) | catalogued as rs1029641588, COSV65121783; called by muse, varscan2
- CDH8 | c.1476C>T p.N492= | Silent (SNP) | VAF 330/686 reads (48%) | catalogued as rs760001992, COSV54860501, COSV54863209; called by muse, varscan2
- CRTAC1 | c.30C>A p.S10= | Silent (SNP) | VAF 236/238 reads (99%) | called by muse, mutect2, varscan2
- CT83 | c.213A>G p.P71= | Silent (SNP) | VAF 74/413 reads (18%) | called by muse, mutect2, varscan2
- DMRTA2 | c.123G>A p.S41= | Silent (SNP) | VAF 406/780 reads (52%) | called by muse, varscan2
- ETNK2 | c.990C>T p.Y330= | Silent (SNP) | VAF 229/493 reads (46%) | catalogued as rs146679279; called by muse, mutect2, varscan2
- FLNC | c.576C>T p.G192= | Silent (SNP) | VAF 180/428 reads (42%) | catalogued as rs554658261, COSV57957070; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJC2 | c.756C>T p.H252= | Silent (SNP) | VAF 315/674 reads (47%) | catalogued as COSV64512706; called by muse, mutect2, varscan2
- IKBIP | c.354T>C p.H118= | Silent (SNP) | VAF 169/385 reads (44%) | called by muse, mutect2, varscan2
- ITIH2 | c.1098A>T p.T366= | Silent (SNP) | VAF 257/589 reads (44%) | called by muse, varscan2
- KCNJ5 | c.90C>T p.R30= | Silent (SNP) | VAF 243/506 reads (48%) | catalogued as rs201886526, COSV100610491; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF20A | c.1575G>A p.K525= | Silent (SNP) | VAF 210/461 reads (46%) | called by muse, mutect2, varscan2
- KRT82 | c.525C>T p.A175= | Silent (SNP) | VAF 686/712 reads (96%) | catalogued as rs979476767; called by muse, varscan2
- MEGF10 | c.3141T>C p.G1047= | Silent (SNP) | VAF 262/506 reads (52%) | called by muse, varscan2
- MUC6 | c.6531G>A p.S2177= | Silent (SNP) | VAF 486/1082 reads (45%) | catalogued as rs746672608, COSV101424385, COSV70145016; called by muse, varscan2
- OR51E2 | c.81C>T p.G27= | Silent (SNP) | VAF 232/528 reads (44%) | called by muse, varscan2
- PCDH8 | c.744C>T p.G248= | Silent (SNP) | VAF 554/1174 reads (47%) | catalogued as COSV58812758; called by muse, varscan2
- PCDHA1 | c.1887C>T p.G629= | Silent (SNP) | VAF 204/508 reads (40%) | catalogued as rs782491014, COSV65375649; called by muse, varscan2
- PLIN3 | c.978G>A p.A326= | Silent (SNP) | VAF 213/514 reads (41%) | catalogued as rs888843093, COSV55734317; called by muse, varscan2
- SCAF1 | c.1695C>T p.H565= | Silent (SNP) | VAF 346/733 reads (47%) | called by muse, mutect2, varscan2
- SLFN11 | c.702C>T p.Y234= | Silent (SNP) | VAF 104/367 reads (28%) | catalogued as rs766440929; called by muse, mutect2, varscan2
- SNX21 | c.306T>G p.P102= | Silent (SNP) | VAF 219/515 reads (43%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3831T>G p.G1277= | Silent (SNP) | VAF 272/1375 reads (20%) | called by muse, varscan2
- SYT1 | c.222C>A p.T74= | Silent (SNP) | VAF 181/440 reads (41%) | called by muse, mutect2, varscan2
- TEX47 | c.477C>T p.D159= | Silent (SNP) | VAF 157/373 reads (42%) | catalogued as rs369625195; called by muse, mutect2, varscan2
- TMPRSS11F | c.984C>T p.F328= | Silent (SNP) | VAF 150/322 reads (47%) | catalogued as rs144406616; called by muse, mutect2, varscan2
- TPD52L3 | c.330A>G p.G110= | Silent (SNP) | VAF 252/578 reads (44%) | called by muse, varscan2
- TREML4 | c.468G>A p.G156= | Silent (SNP) | VAF 151/377 reads (40%) | called by muse, mutect2, varscan2
- WDR26 | c.1545T>C p.Y515= (on ENST00000414423 / NM_001379403.1; = p.Y415= on NM_025160.7) | Silent (SNP) | VAF 210/430 reads (49%) | called by muse, mutect2, varscan2
- WDR87 | c.2733T>C p.S911= | Silent (SNP) | VAF 263/548 reads (48%) | catalogued as rs572092680; called by muse, mutect2, varscan2
- ZFC3H1 | c.1749T>G p.P583= | Silent (SNP) | VAF 149/359 reads (42%) | called by muse, varscan2
- ZNF674 | c.102G>A p.R34= | Silent (SNP) | VAF 170/563 reads (30%) | catalogued as COSV101345062; called by muse, varscan2
- LINC00968 | n.258C>T | RNA (SNP) | VAF 195/480 reads (41%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671244 A>G | 3'Flank (SNP) | VAF 83/180 reads (46%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2712G>A | Intron (SNP) | VAF 116/319 reads (36%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1945T>C | Intron (SNP) | VAF 173/382 reads (45%) | called by muse, mutect2, varscan2
